Surgical pathology report (de-identified scan), TCGA case TCGA-66-2792, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Indivumed, specimen TCGA-66-2792-01A (Primary Tumor).

[page 1 of 2]
Material examined:

Left lung, among others

Clinical diagnosis and question

Left central bronchial carcinoma, originating from lower lobe (squamous cell carcinoma), probably massive exposure to radiation during [REDACTED].

REPORT ON FINDINGS**Macroscopy**

- 1.) Inflated, fixed left lung measuring 14 x 9 cm at the base and up to 27 cm high, central bronchus resection plane located 2.5 cm proximal to the bifurcation of the upper lobe bronchus. Main bronchus largely skeletonized. Pleural fissure shows dorsal cord-shaped area of obliteration, 10 x 5 cm dorsal area of parietal pleura over segment 6 in parts extensively adhesive, in parts loosely attached. At the hilus a 0.5 cm mobile grayish-black node. Lower lobe bronchus constricted at bifurcation and in the proximal section by a central hard pale brown to whitish tumor, max. 5 cm in size, with unclear demarcation and the main mass located in the lower lobe, extending right up to the hilar resection surface and into the main bronchus, whose mucosa proximal to the ostium of the lower lobe shows an irregular protrusion over a section of 1.5 cm and is partly cracked. Tumor distance from central bronchus resection plane at least 2 cm. Involvement of some grayish-black nodes up to 1.5 cm by the tumor. Crossing of pleural fissure and infiltration of adjacent upper lobe. In segment 4, at least 1.2 cm from tumor margin, a 0.6 cm pale brown to gray area, with relatively clear demarcation, suggestive of tumor, distance from pleura at least 1.5 cm. Parenchyma close to tumor in segment 6 indurated and brownish-gray in patches. Extension of lesion to the pleural adhesion zone. Apical parenchyma in segment 1 shows coarsely cystic rarefaction with lacunae or lacuna systems of up to 2.5 cm. Diffuse solidification of lower lobe parenchyma. Subpleural ventromedial area in segment 3 shows a 0.5 cm disk-shaped blackish node. Subpleural ventral area in segment 6 has a similar node 0.9 cm in size.
- 2.) Hilar LN (station 10) left: 1.3 cm node with some surrounding tissue.
- 3.) Pulmonary ligament LN (station 9) left: 1 cm fatty tissue specimen, containing a 0.4 cm blackish node.
- 4.) Subcarinal LN (station 7): 2.3 cm node part with surrounding tissue.
- 5.) Paraaortic LN (station 6) left: 1 cm fatty tissue specimen with a 0.4 cm node.
- 6.) Subaortic LN (aortopulmonary window) (station 5): two lesioned nodes with some surrounding tissue, 1.2 and 1 cm.
- 7.) Low paratracheal LN (station 4) left: two nodes with some surrounding tissue, 0.9 and 0.6 cm.
- 8.) Hilar LN (station 10) right: 1 cm lesioned node part.

Examined:

- 1.) a: Tumor with rest of parenchyma, b: tumor with pleural fissure (upper lobe part color-marked), c: tumor with hilar resection surface (color-marked), d: main bronchus + 2nd tumor focus (peribronchial resection surface color-marked), e: S6 with pleural adhesion + node in S3, f: Segment 8 + node in S6 (halved), g: S1 apical, h: central bronchus resection plane, resection margins of vessels, mobile hilar node, i: 2nd tumor focus, j: tumor with peribronchial node,
- 2.) - 5.) and 7.) and also 8.) All material (in 3. + 5. nodes isolated in each case, in 4. + B. preparations lamellated in each case),
- 6.) node (halved),
- 17 blocks, partly Elastica-van Gieson, PAS, diastase-PAS.

[page 2 of 2]
Microscopy

Description of histological and cytological findings omitted for capacity reasons.

EVALUATION**Primary diagnosis/diagnoses:**

Locally advanced, central bronchopulmonary, histologically poorly differentiated, nonkeratinizing squamous cell carcinoma of the right upper lobe of the lung.

TNM classification according to this picture pT3 pN1 pMX R0, stage IIIA.

C 34.3; M 8070/3.

Secondary diagnosis/diagnoses:

Active chronic and focal organizing pneumonia at the tumor margin. Cicatricial zone or chronic atelectasis peripherally in S6 with overlying adhesion of pleural layers. Subpleural bullous pulmonary emphysema in the apex of the upper lobe. Alternately marked intraalveolar accumulation of brown and anthracotic pigment-storing macrophages (sample 1.)). Lymph nodes with reactive lesions and anthracotic pigment deposits (samples 2.) - 8)).

Remark/addendum:

The resection margin of the bronchus and vessels, the hilar resection surface and the small intrapulmonary lymph nodes of the main preparation and the lymph nodes of sample 2.) are tumor-free.

2. Additional report

An error in the primary diagnosis has to be improved. It is a bifocal bronchopulmonary carcinoma with the main location in the left lower lobe.

1. Additional report

An error in the TNM classification has to be corrected. It is pT2(2) pN1 pMX R0, stage IIB.

Source: NCI Genomic Data Commons file 51f26c24-2e6d-4e09-81bf-66c1b54ffd72 (TCGA-66-2792.C4E1FCB9-CF6D-434E-A38D-57ED9579B588.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).